Somatic mutation profile of tumor specimen MP2PRT-PANZGJ-TMP1-A (aliquot MP2PRT-PANZGJ-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANZGJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,075 days).
Specimen MP2PRT-PANZGJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcac7a74-3d69-4a2d-9325-643df2370da4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANZGJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANZGJ-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8c9726f-5aaf-434f-a679-d979d93d005d

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 9, Silent 6, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 64/304 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 45/422 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ASXL1 | c.2789G>A p.W930* | Nonsense Mutation (SNP) | VAF 145/383 reads (38%) | catalogued as COSV100040040; called by muse, mutect2, varscan2
- C2CD6 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs767620225; called by muse, mutect2, varscan2
- DLGAP3 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 104/405 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs147968723, COSV52394894; called by muse, varscan2
- EFEMP2 | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs2234469; called by muse, mutect2, varscan2
- IGSF9 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 98/320 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.806); catalogued as rs143847211; called by muse, mutect2, varscan2
- SPATA31D1 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 50/475 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs376270710; called by muse, mutect2, varscan2
- ZNF219 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 138/720 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.548); catalogued as rs1419564822; called by muse, mutect2, varscan2
- CDH23 | c.9581_9582insAG p.Y3195Gfs*22 | Frame Shift Ins (INS) | VAF 58/402 reads (14%) | called by mutect2, pindel, varscan2
- SAMD9L | c.2063A>T p.Y688F | Missense Mutation (SNP) | VAF 86/267 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR8B12 | c.615C>T p.D205= | Silent (SNP) | VAF 126/356 reads (35%) | catalogued as rs776638132, COSV60910985; called by muse, mutect2, varscan2
- PTPN5 | c.111G>A p.P37= | Silent (SNP) | VAF 25/187 reads (13%) | catalogued as rs367543235; ClinVar: not provided; called by muse, varscan2
- SLC10A1 | c.18G>A p.A6= | Silent (SNP) | VAF 81/315 reads (26%) | catalogued as rs200228184; called by muse, mutect2, varscan2
- SPRR2B | c.180C>T p.S60= | Silent (SNP) | VAF 148/424 reads (35%) | catalogued as rs1396839658; called by muse, mutect2, varscan2
- TENM1 | c.2976G>A p.P992= | Silent (SNP) | VAF 152/350 reads (43%) | catalogued as rs768641437, COSV64425618; called by muse, mutect2, varscan2
- ZFYVE28 | c.585C>T p.I195= | Silent (SNP) | VAF 189/505 reads (37%) | catalogued as rs535750345, COSV52111628; called by muse, mutect2, varscan2
